Surgical pathology report (de-identified scan), TCGA case TCGA-FY-A76V, project TCGA-THCA (Thyroid Carcinoma), tissue source site International Genomics Consortium, specimen TCGA-FY-A76V-01A (Primary Tumor).

[page 1 of 2]
Sex: Male
D.O.B.:
MRN #
Ref Phy:.....

SPECIMEN INFO

Collected:
Received:
Reported:

SURGICAL PATHOLOGY REPORT

DIAGNOSIS

DIAGNOSIS:

A. Thyroid gland, total thyroidectomy.

Tumor Characteristics:

1. Specimen integrity: Intact.
2. Specimen size: 4.8 x 3.4 x 2.2 cm left lobe, 5.8 x 3.5 x 1.8 cm right lobe, 2.2 x 1.1 x 0.8 cm isthmus.
3. Tumor focality: Multifocal.
4. Dominant tumor:
- a. Tumor laterality: Right lobe/isthmus.
- b. Tumor size: 3.1 x 1.5 x 1.1 cm.
- c. Histologic type: Papillary carcinoma, follicular variant.
- d. Histologic grade: Well differentiated.
- e. Tumor capsule: Present.
- f. Tumor capsular invasion: Not identified.
- g. Lymphovascular space invasion: Not identified.
- h. Perineural invasion: Not identified.
- i. Extrathyroidal extension of tumor: Not identified.
5. Additional tumors:
- a. Papillary microcarcinoma, 0.2 cm, involving left lobe.
- b. Papillary microcarcinoma, 0.25 cm, involving right lobe.
- c. No evidence of lymphovascular invasion or extrathyroidal extension.

Surgical Margin Status:

1. Margins uninvolved by carcinoma: Peripheral
- a. Distance of invasive carcinoma to closest margin: < 1 mm.
2. Margin(s) involved by carcinoma: None.
- Other:
1. pTNM stage: pT2NX.
2. Other significant findings: None.

B. Right inferior parathyroid, resection:
Hypercellular parathyroid gland.
No evidence malignancy.
Frozen section diagnosis confirmed.

Per TSS, follicular variant < 99%.

ICD-O 3

Carcinoma, papillary thyroid

8260/3

Site Thyroid NOS

873.9

8/19/13

Electronic Signature:

CLINICAL INFORMATION

CLINICAL HISTORY:

Preoperative Diagnosis: Hx of thyroid carcinoma

Postoperative Diagnosis:

Symptoms/Radiologic Findings:

SPECIMENS:

- A. Total thyroid
- B. Possible right inferior parathyroid frozen section

SPECIMEN DATA

GROSS DESCRIPTION:

[page 2 of 2]
A. Received label: is a 32 gram total thyroidectomy specimen consisting of a 4.8 x 3.4 x 2.2 cm left lobe, a 5.8 x 3.5 x 1.8 cm right lobe and a 2.2 x 1.1 x 0.6 cm isthmus.

The outer surface is smooth to shaggy and tan-red. The cut surface of the left lobe consists of red-brown beefy parenchyma with a few scattered tan gelatinous nodules ranging from 0.2 cm to 0.6 cm in greatest dimension. No additional lesions are identified.

The cut surface of the right lobe consists of a 3.1 x 1.5 x 1.1 cm fairly well circumscribed gray-white mass which involves the lower pole of the right thyroid lobe and the isthmus. The mass appears abuts the inked outer surface.

The remainder of the cut surface consists of red-brown beefy parenchyma. No additional parenchymal lesions are identified.

The specimen is inked serially sectioned and representative sections are submitted, to include the lesion in its entirety, as labeled: 1-3 - left lobe sequentially submitted from superior to inferior; 4-12 - right lobe sequentially submitted from superior to inferior. The blocks are labeled. Also received in the same container is a green-yellow blue cassette labeled

B. Receive: is a 1.2 x 0.7 x 0.3 cm irregular tan soft tissue with attached adipose tissue which is submitted in toto for frozen section. The frozen section residue is submitted in one cassette labeled

INTRA-OPERATIVE CONSULTATION:
FROZEN SECTION DIAGNOSIS B: 'Parathyroid tissue present'

Source: NCI Genomic Data Commons file 9d6c8037-030c-4007-9eb5-af0e1057ccff (TCGA-FY-A76V.9D4073DB-2494-4472-A3FD-190658622F05.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).